Somatic mutation profile of tumor specimen TCGA-WB-A80P-01A (aliquot TCGA-WB-A80P-01A-11D-A35I-08) from TCGA case TCGA-WB-A80P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 20.8 years (7,608 days).
Specimen TCGA-WB-A80P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2785d84-4429-4f83-80fc-3f7d12860c8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80P-10A (Blood Derived Normal), aliquot TCGA-WB-A80P-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37fc00ba-a05e-4993-a30a-c95759db0b93

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITIH1 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 31/84 reads (37%) | catalogued as rs947579244, COSV56256831; called by muse, mutect2, varscan2
- RP1L1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as rs557203614; called by muse, mutect2, varscan2
- ZNF385D | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1178219211, COSV55750507; called by muse, mutect2, varscan2
- TSPAN15 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2
- CCNDBP1 | c.798G>C p.G266= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV55746589; called by muse, mutect2, varscan2
